Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A6CW, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A6CW-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: M

Age:

Date of surgery:

Localisation: R temporal

Diagnosis: anaplastic oligastrocytoma (grade III WHO)

Name of Pathologist:

ICD-O-3
Oligastrocytoma, anaplastic
9382/3
Site ~~CCF~~ Brain, supratentorial
C71.0
path B Brain, temporal lobe
C71.2
JW 5/16/13

Source: NCI Genomic Data Commons file 4c5f9304-a2cd-411a-aedd-1b018283f9db (TCGA-QH-A6CW.0D917D08-E23D-4158-8049-1B0A9775868B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).